Somatic mutation profile of tumor specimen TCGA-HT-A619-01A (aliquot TCGA-HT-A619-01A-11D-A29Q-08) from TCGA case TCGA-HT-A619, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 51.6 years (18,857 days).
Specimen TCGA-HT-A619-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ce94c8f-80c6-4e91-b0f9-3cd7e972ef97.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-A619-10A (Blood Derived Normal), aliquot TCGA-HT-A619-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64d66db6-6793-42d3-8f24-12fafe59374e

The open-access MAF lists 51 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 9, Nonsense Mutation 3, Frame Shift Ins 3, Frame Shift Del 2, RNA 1, In Frame Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.2694dup p.K899Qfs*32 | Frame Shift Ins (INS) | VAF 77/118 reads (65%) | catalogued as rs1555770200; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 31/77 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NIPBL | c.2422C>T p.R808* | Nonsense Mutation (SNP) | VAF 32/76 reads (42%) | catalogued as rs587783902, CM107654, COSV99243204; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AP4E1 | c.2803T>C p.W935R | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV99957341; called by muse, mutect2, varscan2
- ARHGAP39 | c.1109A>G p.Q370R | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.369); catalogued as COSV99432523; called by muse, mutect2, varscan2
- CELF2 | c.1093G>C p.G365R (on ENST00000416382 / NM_001025077.3; = p.G378R on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100258714; called by muse, mutect2, varscan2
- CFHR3 | c.89A>C p.H30P | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100807869; called by muse, mutect2, varscan2
- CIT | c.4396A>G p.K1466E | Missense Mutation (SNP) | VAF 133/296 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV99950648; called by muse, mutect2, varscan2
- DBH | c.599C>G p.P200R | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV55042399, COSV99708175; called by muse, mutect2, varscan2
- EGF | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV99491505; called by muse, mutect2, varscan2
- EPHA3 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 142/345 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as rs773846066, COSV60708175; called by muse, mutect2, varscan2
- FBXL13 | c.2157A>C p.L719F | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.201); catalogued as COSV100502290; called by muse, mutect2, varscan2
- HEATR5B | c.2732G>A p.G911D | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99250450; called by muse, mutect2, varscan2
- HERC1 | c.11306G>A p.G3769E | Missense Mutation (SNP) | VAF 20/21 reads (95%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV101497096; called by muse, mutect2, varscan2
- MAP1B | c.5891C>G p.T1964S | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.036); catalogued as COSV57093948, COSV99703067; called by muse, mutect2
- MLKL | c.722+1G>A p.X241_splice | Splice Site (SNP) | VAF 140/307 reads (46%) | catalogued as rs144019045; called by muse, mutect2, varscan2
- MUC16 | c.7739C>A p.T2580K | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV101202237; called by muse, mutect2
- MYO10 | c.3833G>A p.G1278E | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99946602; called by muse, mutect2, varscan2
- NCKAP1 | c.1399A>G p.M467V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV100720616; called by muse, mutect2, varscan2
- NECTIN3 | c.400A>G p.T134A | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.088); catalogued as COSV100162835; called by muse, mutect2, varscan2
- OLFML2A | c.1474C>T p.R492W | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs534548756, COSV99992342; called by muse, mutect2, varscan2
- PELI2 | c.1133C>G p.A378G | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.245); catalogued as COSV99954122; called by muse, mutect2, varscan2
- PHLDB2 | c.3149C>T p.T1050M (on ENST00000393925 / NM_001134439.2; = p.T1007M on NM_145753.2) | Missense Mutation (SNP) | VAF 65/110 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs776120319, COSV101208794; called by muse, mutect2, varscan2
- PRPF40B | c.2372A>G p.H791R (on ENST00000380281; = p.H778R on NM_012272.3) | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.95); catalogued as rs764584707, COSV53306328; called by muse, mutect2, varscan2
- REG1B | c.370T>C p.W124R | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV100521559; called by muse, mutect2, varscan2
- SLC4A1AP | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs752001371, COSV58134052; called by muse, mutect2, varscan2
- SLC6A19 | c.1352C>T p.P451L | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs1344159365, COSV100443706; called by muse, mutect2
- SPRY4 | c.705G>A p.W235* (on ENST00000434127 / NM_001127496.3; = p.W258* on NM_030964.4) | Nonsense Mutation (SNP) | VAF 30/58 reads (52%) | catalogued as COSV100702254; called by muse, mutect2, varscan2
- ST3GAL3 | c.484C>T p.R162C (on ENST00000361392 / NM_174964.4; = p.R147C on NM_006279.5) | Missense Mutation (SNP) | VAF 55/67 reads (82%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as rs200149990, COSV53518004; called by muse, mutect2, varscan2
- SYNRG | c.2030G>A p.G677E | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.992); catalogued as rs1423585493; called by muse, mutect2, varscan2
- TAOK1 | c.2125C>T p.R709* | Nonsense Mutation (SNP) | VAF 55/131 reads (42%) | catalogued as rs1347078601, COSV99914958; called by muse, mutect2, varscan2
- THOC6 | c.94G>A p.V32I | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs778050811, COSV50188295; called by muse, mutect2, varscan2
- WASF3 | c.213C>G p.D71E | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV100099769; called by muse, mutect2, varscan2
- ZNF148 | c.745C>G p.H249D | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100642211, COSV62302704; called by muse, mutect2, varscan2
- ASB15 | c.1039_1040del p.D347Rfs*2 | Frame Shift Del (DEL) | VAF 52/209 reads (25%) | called by mutect2, pindel, varscan2
- MUC2 | c.2281G>A p.A761T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PPP2R2A | c.1169_1186del p.T390_R395del | In Frame Del (DEL) | VAF 16/54 reads (30%) | called by mutect2, varscan2
- SLCO2B1 | c.1149_1150dup p.S384Cfs*205 | Frame Shift Ins (INS) | VAF 65/167 reads (39%) | called by mutect2, pindel, varscan2
- TSPAN32 | c.698dup p.K234Qfs*45 | Frame Shift Ins (INS) | VAF 63/157 reads (40%) | called by mutect2, pindel, varscan2
- WNT16 | c.82del p.Q28Kfs*25 | Frame Shift Del (DEL) | VAF 31/62 reads (50%) | called by mutect2, pindel, varscan2
- ABCB5 | c.2736G>A p.S912= (on ENST00000404938 / NM_001163941.2; = p.S467= on NM_178559.6) | Silent (SNP) | VAF 59/221 reads (27%) | catalogued as rs760878587, COSV51707168, COSV51708453; called by muse, mutect2, varscan2
- CCP110 | c.393G>A p.T131= | Silent (SNP) | VAF 34/58 reads (59%) | catalogued as rs759448367, COSV101195364; called by muse, mutect2
- COX4I2 | c.339T>C p.I113= | Silent (SNP) | VAF 30/129 reads (23%) | catalogued as COSV101064297; called by muse, mutect2, varscan2
- CRTC1 | c.1074G>A p.A358= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs1412033388, COSV100119722; called by muse, mutect2, varscan2
- CRYBB3 | c.555C>T p.D185= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as rs140985147; called by muse, mutect2
- EPHB6 | c.69G>T p.L23= | Silent (SNP) | VAF 9/112 reads (8%) | catalogued as COSV101236009; called by muse, mutect2
- METTL17 | c.13C>T p.L5= | Silent (SNP) | VAF 50/82 reads (61%) | catalogued as COSV100228414; called by muse, mutect2, varscan2
- PCDHA3 | c.1914C>T p.D638= | Silent (SNP) | VAF 11/170 reads (6%) | catalogued as COSV63540718; called by muse, mutect2
- PXDNL | c.4215C>T p.A1405= | Silent (SNP) | VAF 135/262 reads (52%) | catalogued as rs371941977; called by muse, mutect2, varscan2
- RGS3 | c.3081-118C>T | Intron (SNP) | VAF 80/188 reads (43%) | catalogued as COSV100637117; called by muse, mutect2, varscan2
- SSPOP | n.12263G>A | RNA (SNP) | VAF 9/59 reads (15%) | catalogued as rs555123515, COSV65127629; called by muse, mutect2, varscan2
